Somatic mutation profile of tumor specimen MP2PRT-PASZLD-TMP1-A (aliquot MP2PRT-PASZLD-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASZLD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (982 days).
Specimen MP2PRT-PASZLD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8275bee-6a31-4385-a0b0-268534dab5a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZLD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZLD-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b86e916-cc9a-407b-a273-8bc23fa7cee2

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL22A1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 154/424 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200816628, COSV100280467, COSV57327951; called by muse, mutect2, varscan2
- DNAH9 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 19/267 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs892535226, COSV52353078; called by muse, mutect2
- LGSN | c.1313T>C p.L438S | Missense Mutation (SNP) | VAF 41/403 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC22A14 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 16/576 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2
- SPATA31A3 | c.1942T>A p.S648T | Missense Mutation (SNP) | VAF 76/656 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- HNRNPH2 | c.1170C>T p.G390= | Silent (SNP) | VAF 63/634 reads (10%) | catalogued as rs782414019; called by muse, mutect2, varscan2
- KCNN3 | c.2217G>A p.P739= (on ENST00000618040 / NM_001204087.1; = p.P724= on NM_002249.6) | Silent (SNP) | VAF 58/338 reads (17%) | catalogued as rs199920438, COSV55223592; called by mutect2, varscan2
- ALAS2 | c.-9A>T | 5'UTR (SNP) | VAF 79/591 reads (13%) | called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins CTT | 5'Flank (INS) | VAF 26/104 reads (25%) | called by pindel, varscan2
